Somatic mutation profile of tumor specimen MBCProject_4634_T1_WES (aliquot MBCProject_4634_T1_WES_1) from CMI case MBCProject_4634, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 35.2 years (12,859 days).
Specimen MBCProject_4634_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9fddcb-1ecf-4f7b-baa3-e622b82ef5db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_4634_SALIVA (Saliva), aliquot MBCProject_4634_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7286774-568e-42c9-91be-f89e634d7a1b

The open-access MAF lists 126 somatic variants for this specimen: 89 protein-altering or splice-affecting, 24 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 24, Intron 9, Frame Shift Del 4, In Frame Del 3, Splice Site 2, 5'UTR 2, RNA 2, Frame Shift Ins 2, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABL1 | c.2329C>G p.R777G | Missense Mutation (SNP) | VAF 40/48 reads (83%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100584157; called by muse, mutect2, varscan2
- ASCL1 | c.269G>T p.R90L | Missense Mutation (SNP) | VAF 67/118 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1245236382; called by muse, mutect2, varscan2
- ATP6V0A4 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1393351118; called by muse, mutect2, varscan2
- ATP8A2 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 43/55 reads (78%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.987); catalogued as rs781564289; called by muse, mutect2, varscan2
- CAMSAP3 | c.3488G>A p.R1163H | Missense Mutation (SNP) | VAF 50/63 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436850140, COSV50331592; called by muse, mutect2, varscan2
- CCDC181 | c.1121_1122del p.I374Sfs*3 | Frame Shift Del (DEL) | VAF 59/216 reads (27%) | catalogued as rs113798135; called by mutect2, pindel, varscan2
- CDH23 | c.4918G>A p.E1640K | Missense Mutation (SNP) | VAF 112/148 reads (76%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs773449705; called by muse, mutect2, varscan2
- CSMD1 | c.9689G>T p.S3230I (on ENST00000520002; = p.S3229I on NM_033225.6) | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as rs781377775; called by muse, mutect2, varscan2
- CSMD1 | c.6289G>A p.G2097R (on ENST00000520002; = p.G2096R on NM_033225.6) | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1392273583, COSV59326816; called by muse, mutect2, varscan2
- FMN2 | c.215C>G p.A72G | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100144512; called by muse, mutect2, varscan2
- GRK2 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV57752716; called by muse, mutect2, varscan2
- IMPG1 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as COSV64054078, COSV64057361; called by muse, mutect2, varscan2
- ITSN1 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.602); catalogued as rs762631985, COSV101180633; called by muse, varscan2
- KBTBD7 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 153/210 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267096; called by muse, mutect2, varscan2
- KCNT2 | c.307C>A p.P103T | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1161233570; called by muse, mutect2, varscan2
- NFKBIZ | c.1559G>C p.C520S | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs1365903584; called by muse, mutect2, varscan2
- NOP9 | c.1090A>T p.I364F | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV51868132; called by muse, mutect2, varscan2
- OR2C3 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100825565; called by muse, mutect2, varscan2
- OR51F2 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100438024; called by muse, mutect2, varscan2
- PCCB | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52444264; called by muse, mutect2, varscan2
- PCDHA2 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 84/107 reads (79%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV65371830; called by muse, mutect2, varscan2
- PGBD2 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1277643554; called by muse, mutect2
- PNPLA8 | c.995A>G p.Q332R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as rs1041520737; called by muse, mutect2
- PRMT1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 87/212 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV54919685; called by muse, mutect2, varscan2
- SLC25A41 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 89/111 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs766499255; called by muse, mutect2, varscan2
- SLC2A13 | c.609T>A p.N203K | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV55117514; called by muse, mutect2, varscan2
- SYT10 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.415); catalogued as rs755675734, COSV57339421; called by muse, mutect2, varscan2
- TRPC3 | c.929C>T p.T310M (on ENST00000379645 / NM_001366479.2; = p.T237M on NM_003305.2) | Missense Mutation (SNP) | VAF 80/244 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs200027824; called by muse, mutect2, varscan2
- USF2 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99723504; called by muse, mutect2, varscan2
- USH2A | c.9413del p.G3138Afs*22 | Frame Shift Del (DEL) | VAF 85/205 reads (41%) | catalogued as CM155006, COSV56438014; called by mutect2, pindel, varscan2
- USP22 | c.1229A>G p.K410R | Missense Mutation (SNP) | VAF 65/77 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54948261; called by muse, mutect2, varscan2
- VCX3A | c.287G>C p.S96T | Missense Mutation (SNP) | VAF 76/534 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as rs1237851216; called by muse, varscan2
- ZNF835 | c.429C>G p.C143W | Missense Mutation (SNP) | VAF 70/212 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101606358; called by muse, mutect2, varscan2
- ADGRB2 | c.2646-2A>G p.X882_splice | Splice Site (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- ADGRG4 | c.7880T>C p.F2627S | Missense Mutation (SNP) | VAF 56/232 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ANKRD30B | c.2700_2704dup p.T902Rfs*7 | Frame Shift Ins (INS) | VAF 28/64 reads (44%) | called by mutect2, varscan2
- ANOS1 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- APEH | c.142_145+20del p.X48_splice | Splice Site (DEL) | VAF 43/74 reads (58%) | called by mutect2, pindel, varscan2
- BAZ2A | c.2020G>T p.G674C | Missense Mutation (SNP) | VAF 176/220 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1C | c.2976_2990del p.N992_L997delinsK | In Frame Del (DEL) | VAF 32/286 reads (11%) | called by mutect2, pindel
- CALCRL | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CD200 | c.860A>T p.H287L (on ENST00000473539 / NM_001004196.3; = p.H262L on NM_005944.7 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/202 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CGN | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNGA2 | c.1626C>A p.S542R | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNKSR1 | c.96_109del p.L33Pfs*55 | Frame Shift Del (DEL) | VAF 89/269 reads (33%) | called by mutect2, pindel, varscan2
- CRAMP1 | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CYB561D1 | c.204_209del p.E69_A70del | In Frame Del (DEL) | VAF 72/97 reads (74%) | called by mutect2, pindel, varscan2
- DDX58 | c.383C>G p.S128C | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- DMXL2 | c.7960A>G p.K2654E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2
- DPY19L4 | c.1931A>G p.E644G | Missense Mutation (SNP) | VAF 56/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENPP5 | c.498A>T p.R166S | Missense Mutation (SNP) | VAF 91/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS15L1 | c.2203T>C p.F735L | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ERLEC1 | c.703_747del p.E235_Y249del | In Frame Del (DEL) | VAF 54/128 reads (42%) | called by mutect2, pindel
- F8 | c.5800A>T p.N1934Y | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FAM83E | c.173_176del p.F58Sfs*40 | Frame Shift Del (DEL) | VAF 57/216 reads (26%) | called by mutect2, pindel, varscan2
- LDHD | c.479C>G p.A160G | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRB1 | c.173A>G p.Q58R (on ENST00000427581; = p.Q22R on NM_006669.6) | Missense Mutation (SNP) | VAF 101/314 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- LRRK2 | c.5005G>C p.V1669L | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- LTBP3 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MAGEC1 | c.3323A>T p.K1108I | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- MAGEC1 | c.3324A>T p.K1108N | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- MTMR14 | c.568C>A p.H190N | Missense Mutation (SNP) | VAF 119/275 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- OGT | c.1685G>T p.S562I | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- OR10C1 | c.544A>T p.I182F (on ENST00000622521; = p.I180F on NM_013941.3) | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR4X2 | c.142G>C p.G48R | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- PCMTD1 | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 100/209 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PDCD1LG2 | c.17T>G p.L6R | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PHF6 | c.681A>C p.K227N (on ENST00000332070 / NM_032458.3; = p.K228N on NM_032335.3) | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.255); called by muse, mutect2
- PLIN1 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PPP6R3 | c.908A>T p.K303M | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PTCHD3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- QSER1 | c.3184G>A p.E1062K (on ENST00000399302; = p.E1191K on NM_001076786.3) | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RAB11FIP2 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- RBM3 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- REG4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); called by muse, mutect2
- RINL | c.386G>C p.R129T (on ENST00000591812 / NM_001195833.2; = p.R15T on NM_198445.4) | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RPL26L1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, varscan2
- SEMA4C | c.1321A>C p.I441L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SLC44A2 | c.1646G>C p.W549S | Missense Mutation (SNP) | VAF 112/142 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SNX9 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 86/112 reads (77%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- SPEN | c.1982G>T p.W661L | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SPRING1 | c.86A>C p.Y29S | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- STXBP6 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- TENM4 | c.3694C>G p.P1232A | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- TJP3 | c.375C>G p.D125E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2
- TP53 | c.241dup p.T81Nfs*68 | Frame Shift Ins (INS) | VAF 71/120 reads (59%) | called by mutect2, pindel, varscan2
- TRIM17 | c.1169T>C p.V390A | Missense Mutation (SNP) | VAF 69/216 reads (32%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TRMT5 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ZBED9 | c.2349A>T p.K783N | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ACACB | c.3324C>G p.T1108= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as rs774656373; called by muse, mutect2, varscan2
- ALK | c.3411A>T p.G1137= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- CNNM1 | c.717C>T p.F239= | Silent (SNP) | VAF 63/85 reads (74%) | called by muse, mutect2, varscan2
- CSNK1G3 | c.514C>A p.R172= | Silent (SNP) | VAF 18/165 reads (11%) | catalogued as COSV100631896; called by muse, mutect2, varscan2
- DTHD1 | c.1615C>T p.L539= (on ENST00000456874; = p.L374= on NM_001136536.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 77/96 reads (80%) | catalogued as rs1331685734; called by muse, mutect2, varscan2
- FLNC | c.6609C>T p.R2203= | Silent (SNP) | VAF 105/227 reads (46%) | catalogued as rs374101315; called by muse, mutect2, varscan2
- FNDC5 | c.522C>T p.R174= | Silent (SNP) | VAF 33/110 reads (30%) | called by muse, mutect2, varscan2
- FTHL17 | c.459G>T p.V153= | Silent (SNP) | VAF 74/177 reads (42%) | called by muse, varscan2
- HSPA12A | c.318T>C p.T106= | Silent (SNP) | VAF 97/205 reads (47%) | called by muse, mutect2, varscan2
- KIAA1671 | c.4620G>A p.T1540= | Silent (SNP) | VAF 112/147 reads (76%) | catalogued as rs916290152; called by muse, mutect2, varscan2
- KRTAP13-4 | c.327C>T p.S109= | Silent (SNP) | VAF 74/149 reads (50%) | catalogued as rs1473843642; called by muse, mutect2, varscan2
- MAN2B2 | c.267G>C p.S89= | Silent (SNP) | VAF 50/63 reads (79%) | catalogued as rs375473664; called by muse, mutect2, varscan2
- MUC21 | c.1023G>C p.G341= | Silent (SNP) | VAF 167/456 reads (37%) | called by muse, mutect2, varscan2
- PI16 | c.741G>A p.E247= | Silent (SNP) | VAF 32/127 reads (25%) | called by muse, mutect2, varscan2
- PKD1L1 | c.5637C>T p.H1879= | Silent (SNP) | VAF 80/230 reads (35%) | catalogued as rs138494625; called by muse, mutect2, varscan2
- PPP2R3A | c.252A>G p.G84= | Silent (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2, varscan2
- SLC8A2 | c.846G>T p.L282= | Silent (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- SNX29 | c.649C>T p.L217= | Silent (SNP) | VAF 109/296 reads (37%) | called by muse, mutect2, varscan2
- SNX32 | c.99A>C p.A33= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as rs369776314; called by muse, mutect2, varscan2
- STXBP6 | c.204T>C p.F68= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as rs1374027734; called by muse, mutect2, varscan2
- TOE1 | c.828C>T p.S276= | Silent (SNP) | VAF 56/225 reads (25%) | called by muse, mutect2, varscan2
- TRIM72 | c.1269C>A p.V423= | Silent (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2, varscan2
- TSPAN12 | c.153A>G p.V51= | Silent (SNP) | VAF 53/252 reads (21%) | catalogued as rs770789679; called by muse, mutect2, varscan2
- UMODL1 | c.1443C>A p.S481= | Silent (SNP) | VAF 83/164 reads (51%) | called by muse, mutect2, varscan2
- AQP12A | c.-1G>A | 5'UTR (SNP) | VAF 61/140 reads (44%) | catalogued as rs145786292; called by muse, mutect2, varscan2
- BNIP2 | c.-58+269_-58+277del | Intron (DEL) | VAF 5/9 reads (56%) | called by mutect2, varscan2
- CFAP74 | c.4653+271T>G | Intron (SNP) | VAF 51/103 reads (50%) | called by muse, mutect2, varscan2
- FSHR | c.374+2603A>C | Intron (SNP) | VAF 73/172 reads (42%) | called by muse, mutect2, varscan2
- GASK1A | c.1413+108_1413+113del | Intron (DEL) | VAF 18/93 reads (19%) | called by mutect2, pindel, varscan2
- LSM8 | c.31+49C>T | Intron (SNP) | VAF 14/24 reads (58%) | catalogued as rs752616329; called by muse, varscan2
- NECTIN3-AS1 | n.926C>A | RNA (SNP) | VAF 24/85 reads (28%) | called by muse, mutect2
- PMM2 | c.347+29A>C | Intron (SNP) | VAF 39/147 reads (27%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-228C>A | Intron (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2, varscan2
- RIMS2 | c.2084-942G>C | Intron (SNP) | VAF 10/118 reads (8%) | catalogued as rs910081914; called by muse, mutect2
- RPL26P30 | n.975G>A | RNA (SNP) | VAF 14/52 reads (27%) | catalogued as rs533339814; called by muse, varscan2
- SEC63 | c.1935+17C>T | Intron (SNP) | VAF 67/92 reads (73%) | called by muse, mutect2, varscan2
- ZNF195 | c.-45C>G | 5'UTR (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
